Somatic mutation profile of tumor specimen TARGET-20-PASPIN-09A (aliquot TARGET-20-PASPIN-09A-01D) from TARGET case TARGET-20-PASPIN, project TARGET-AML (Acute Myeloid Leukemia). Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow.
Specimen TARGET-20-PASPIN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09ac0b2f-6c25-4652-99dd-ec169f5659fc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASPIN-14A (Bone Marrow Normal), aliquot TARGET-20-PASPIN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63727e73-cd4a-469a-b664-4ece706b154f

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.9268G>T p.E3090* | Nonsense Mutation (SNP) | VAF 80/180 reads (44%) | catalogued as COSV56471679; called by muse, mutect2, varscan2
- MYC | c.176C>A p.P59Q (on ENST00000377970; = p.P74Q on NM_002467.6) | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
